Somatic mutation profile of tumor specimen TARGET-30-PATMSR-01A (aliquot TARGET-30-PATMSR-01A-01D) from TARGET case TARGET-30-PATMSR, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 1.3 years (480 days).
Specimen TARGET-30-PATMSR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0bb7fe27-c5a1-48ee-bd50-413d2aece373.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATMSR-10A (Blood Derived Normal), aliquot TARGET-30-PATMSR-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e102dcf6-8fda-4871-826d-9b9fd5c3d037

The open-access MAF lists 3 somatic variants for this specimen: 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID2 | c.*2506T>C | 3'UTR (SNP) | VAF 70/181 reads (39%) | catalogued as COSV57615226; called by muse, mutect2, varscan2
- CBL | c.*3187C>A | 3'UTR (SNP) | VAF 12/152 reads (8%) | called by muse, mutect2
- DOCK8 | c.1797+41C>A | Intron (SNP) | VAF 16/78 reads (21%) | catalogued as COSV66624119; called by muse, mutect2, varscan2
